Surgical pathology report (de-identified scan), TCGA case TCGA-D7-A4YY, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-A4YY-01A (Primary Tumor).

[page 1 of 2]
Patient: XXX

PESEL: XXX

Age:

Gender: M

Examination result No.

Unit in charge: I

Physician in charge:

Clinical diagnosis (suspicion) **Gastric cancer.**

Date of admission:

108-0-3

Adeno carcinoma, NOS 8140/3

Site: Stomach, antrum C12.3

w
12/13/12

Material:

- 1) Material: stomach, stomach with the tumour. Method of collection: Total organ resection
- 2) 1) Material: omentum, Method of collection: Partial organ resection
- 3) 1) Material: intestine, anastomosis rings - oesophagus and intestine. Method of collection: Partial organ resection
- 4) 1) Material: lymph nodes – intra-abdominal lymph nodes, lymph nodes from the region of the common hepatic artery. Method of collection: Partial organ resection

Histopathological diagnosis:

Examination performed on:

Stomach adenocarcinoma partially mucinous. Adeno, NOS per VSS. (mucinous <10%).

Intestinal type acc. to Lauren. Signs of vascular invasion.

Cancer metastases to lymph nodes (No VII/XXII).

Incision lines free of neoplastic lesions.

G3, pT3, pN3a. (8480/3 T-63000)*

Macroscopic description:

1. The specimen consisting of the stomach, after being incised along the larger curvature, sized 13 x 20.5 cm.
Ulcerated tumour sized 5.5 x 4.5 x 1.5 cm found in the pyloric region.
Tumour penetrates the full thickness of the stomach wall, without reaching beyond the serosa. Distance from the proximal end: 8.5 cm, from distal end: 0.5 cm.
2. The omentum sized 41 x 15 x 2 cm.
3. Two tissue rings sized: 2.5 x 1.5 x 1 cm, 1.5 x 1.2 x 1 cm.
4. Surgical specimen sized: 1 x 1 x 0.5 cm: lymph node.

Case #	108-0-3	Yes	No
Histology Discrepancy			
Case Labeled	QUALIFIED		

[page 2 of 2]
Microscopic description:

1. Gastric partly mucinous adenocarcinoma (G3).

Cancer invades the muscularis propria, subserosa, pergastric fat tissue, without reaching beyond the serosa.

Intestinal type acc. to Signs of vascular invasion. The mucosa off the tumour showing: Gastritis chronica superficialis. Proximal and distal incision lines free of neoplastic lesions. LYMPH NODES:

1,2 (around cardia): Lymphonodulitis reactiva No (III). Clusters of epithelioid cells in one of the nodes.

3 - (lesser curvature): Metastases carcinomatosae in lymphonodis (No II/VIII). Infiltratio carcinomatosa capsulae lymphonodi et teale adiposae perinodalis.

Clusters of epithelioid cells in three nodes.

4 - (greater curvature): Metastases carcinomatosae in lymphonodis No (II/VI). Infiltratio carcinomatosa capsulae lymphonodi.

Clusters of epithelioid cells in one of the nodes.

6 - (peripyloric): Metastases carcinomatosae in lymphonodis No (III/IV).

Source: NCI Genomic Data Commons file 2b5b36a2-88ba-473e-9216-9653d6ae8302 (TCGA-D7-A4YY.37C512BD-6804-4608-9D76-14D74FB3E07A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).